Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-5407, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-5407-01A (Primary Tumor).

PATIENT HISTORY:

Colon mass.

PRE-OP DIAGNOSIS: Colon mass.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Laparoscopic colectomy attempted, open right colectomy done.

FINAL DIAGNOSIS:**SEGMENT OF TERMINAL ILEUM AND RIGHT HEMICOLECTOMY -**

- A. INVASIVE WELL-DIFFERENTIATED COLON ADENOCARCINOMA**
- a. 0.9 CM INVASIVE TUMOR INTO SUB-MUCOSA
- b. INVASIVE CARCINOMA ARISING IN A 2.5 CM GREATEST DIMENSION TUBULOVILLOUS ADENOMA WITH SERRATED FEATURES.
- B. ADDITIONAL NON-INVASIVE ADENOMAS: 2 TUBULOVILLOUS ADENOMAS (2.9 CM AND 1.5 CM) AND 1 TUBULAR ADENOMA (1.0 CM).**
- C. RESECTION MARGINS ARE FREE OF CARCINOMA AND ADENOMA.**
- D. NO ANGIOLYMPHATIC INVASION IS SEEN.**
- E. SIXTEEN BENIGN LYMPH NODES (0/16).**
- F. PATHOLOGIC STAGE; T1 N0 MX.**
- G. TERMINAL ILEUM WITH NO SIGNIFICANT PATHOLOGIC CHANGE.**
- H. APPENDIX WITH TUBULAR CARCINOID TUMOR.**
- a. TUBULAR CARCINOID ARISES IN THE APPENDIX TIP.
- b. TUBULAR CARCINOID MEASURES 3MM.
- c. (see comment).

COMMENT:

Immunohistochemical stains were performed on the appendix (slide C). Appendix tumor cells are weakly positive for glucagon and positive for CDX2, mCEA, pancytokeratin, and synaptophysin. It is negative for estrogen receptor, progesterone receptor, chromogranin, and p53. These findings are compatible with a tubular carcinoid.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS**

SPECIMEN TYPE:	Right hemicolectomy
SPECIMEN LENGTH:	22.5 cm
TUMOR SITE:	Cecum
TUMOR CONFIGURATION:	Arising in a polyp
TUMOR SIZE:	Greatest dimension: 0.9 cm
INTACTNESS OF MESORECTUM:	Not applicable
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	Low-grade (well to moderately differentiated)
PATHOLOGIC STAGING (pTNM):	pT1 pN0 Number of nodes examined: 16 Number of nodes involved: 0 pMX
MARGINS:	Proximal margin uninvolved by invasive carcinoma Distal margin uninvolved by invasive carcinoma Circumferential (radial) margin - Not applicable
ANGIOLYMPHATIC INVASION:	Absent
PERINEURAL INVASION:	Absent
TUMOR BORDER CONFIGURATION:	Pushing
TUMORAL LYMPHOCYTIC RESPONSE:	None
ADDITIONAL PATHOLOGIC FINDINGS:	Adenoma(s) Other polyps (type[s]): 2 tubulovillous adenomas, 1 tubular adenoma.

SPECIAL PROCEDURES:**Microdissection Genotyping****Interpretation****Molecular Anatomic Pathology testing for Microsatellite Instability:**

- A. No microsatellite instability detected (Microsatellite stable)**
- B. Immunohistochemistry for the hMLH1, hMSH2 and hMSH6 showed preserved gene expression**

Note:

The specimen was analyzed by PCR for microsatellite instability because the patient met one or more of the recently recommended criteria for testing (1). The five recommended dinucleotide and mononucleotide polymorphisms were utilized to assess for microsatellite instability (MSI). ZERO of five markers showed evidence of microsatellite instability.

Additionally, the immunohistochemistry for hMLH1, hMSH2 and hMSH6 demonstrated preserved nuclear staining in the neoplastic epithelium, as compared to the positive/intact nuclear staining in the benign epithelium.

Source: NCI Genomic Data Commons file 97cfb578-7129-4d75-85ec-8b0a06cb338f (TCGA-AZ-5407.6C27F8B9-9E3C-4665-A176-A4679EED1FA9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).